Gene-level copy-number profile of tumor specimen ALCH-B0H7-TTP1-A from ALCHEMIST case ALCH-B0H7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 59.6 years (21,759 days).
Specimen ALCH-B0H7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 86380204-b3e3-45d4-bdc0-4ec851d4503b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0H7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/06dba497-2d0a-4900-9693-017fb36189ac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 2,824; copy number 2: 29,468; copy number 3: 17,757; copy number 4: 4,401; copy number 5: 1,607; copy number 6: 1,351; copy number 7: 270; copy number 8: 151; copy number 9: 44; copy number 10: 37; copy number 11: 209; copy number 12: 72; copy number 14: 9; copy number 15: 29; copy number 16: 5; copy number 18: 28; copy number 19: 32; copy number 22: 7; copy number 44: 6; copy number 45: 34; copy number 48: 10; copy number 56: 39.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–180,982,611, 3 genes: AC091874.2, AC091874.1, ARPP19P1.
- chr16:981,770–1,113,399, 8 genes: SOX8, AC009041.1, SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1, AL031598.1.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,940 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–3,955,262, 210 genes, copy number 5 (broad region; genes not listed).
- chr1:5,862,672–10,181,239, 117 genes, copy number 5 (broad region; genes not listed).
- chr7:21,428,043–21,514,822, 2 genes, copy number 5: SP4, MIR1183.
- chr7:139,025,706–139,228,605, 8 genes, copy number 5: ZC3HAV1L, ZC3HAV1, AC018644.1, TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2.
- chr8:66,021,553–101,169,629, 562 genes, copy number 5–19 (broad region; genes not listed).
- chr8:110,334,743–118,111,826, 47 genes, copy number 6: AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1.
- chr8:120,812,219–129,786,624, 138 genes, copy number 5–12 (within-gene range 4–12) (broad region; genes not listed).
- chr9:38,147,428–40,153,147, 52 genes, copy number 6–11: U8, AL135785.1, ALDH1B1, IGFBPL1, AL390726.5, ARMC8P1, TCEA1P3, GAS2L1P1, VN1R48P, AL390726.1, FAM220BP, AL390726.4, FAM95C, AL390726.3, AL390726.2, SNX18P3, ANKRD18A, FAM201A, YWHABP1, RNU6-765P, AL845311.1, VN2R3P, CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1, FGF7P3, BX664615.2, RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr9:41,233,755–60,547,154, 56 genes, copy number 8: MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1, CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1, BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1, FP325317.1, FP325317.2, BX088702.1.
- chr9:61,854,148–62,096,920, 1 gene, copy number 5 (within-gene range 4–5): FAM27C.
- chr9:61,944,232–66,179,474, 101 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr11:71,382,601–71,629,421, 18 genes, copy number 5: ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1, KRTAP5-11, KRTAP5-14P, OR7E87P, UNC93B6, OR7E4P, AP000867.3.
- chr11:75,815,210–76,144,232, 1 gene, copy number 6 (within-gene range 4–6): UVRAG.
- chr11:75,911,204–80,327,911, 82 genes, copy number 6 (broad region; genes not listed).
- chr12:23,108,458–23,251,499, 3 genes, copy number 5 (within-gene range 3–5): AC087258.1, AC087235.2, AC087235.1.
- chr12:24,810,024–28,825,831, 89 genes, copy number 44–56 (within-gene range 44–72) (broad region; genes not listed).
- chr12:31,382,226–41,072,415, 113 genes, copy number 5 (broad region; genes not listed).
- chr12:42,929,848–48,789,037, 139 genes, copy number 5–6 (broad region; genes not listed).
- chr12:57,747,727–57,756,013, 1 gene, copy number 16 (within-gene range 3–16): CDK4.
- chr12:57,755,103–57,772,119, 3 genes, copy number 16 (within-gene range 3–16): MARCHF9, CYP27B1, METTL1.
- chr12:60,150,187–60,419,293, 5 genes, copy number 7: AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2.
- chr12:65,466,820–97,761,859, 481 genes, copy number 5–18 (within-gene range 3–18) (broad region; genes not listed).
- chr12:119,989,869–120,119,000, 5 genes, copy number 5: BICDL1, Metazoa_SRP, AC004812.1, RAB35, AC004812.2.
- chr12:130,953,907–132,131,639, 49 genes, copy number 5 (within-gene range 1–5): ADGRD1, AC073862.3, AC073862.4, AC073862.5, AC073862.1, AC073862.2, AC078925.4, ADGRD1-AS1, AC078925.2, AC078925.3, AC078925.1, LINC01257, AC126564.1, RPS6P20, AC092850.1, LINC02415, RNA5SP376, LINC02370, AC140118.2, AC140118.1, AC073578.4, AC073578.2, AC073578.1, AC073578.3, AC140063.1, AC117500.5, AC117500.3, LINC02414, AC117500.4, RNA5SP377, AC117500.1, RPS6P21, SFSWAP, AC117500.2, RNA5SP378, RNU6-1017P, MMP17, AC131009.2, ULK1, AC131009.4, AC131009.1, PUS1, AC131009.3, EP400, SNORA49, AC137590.1, AC137590.2, EP400P1, AC138466.5.
- chr13:85,837,126–114,337,626, 373 genes, copy number 5–6 (broad region; genes not listed).
- chr14:32,934,396–41,556,055, 128 genes, copy number 6–22 (within-gene range 2–22) (broad region; genes not listed).
- chr14:42,807,378–43,596,683, 7 genes, copy number 11: YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, KRT8P2, AL358913.1, ARHGAP16P.
- chr18:23,134,564–33,441,101, 150 genes, copy number 5 (broad region; genes not listed).
- chr19:34,675,717–35,154,302, 33 genes, copy number 5: AC020910.6, ZNF302, AC020910.5, ZNF181, ZNF599, AC020910.3, LINC01801, AC008555.1, AC008555.5, AC008555.2, AC008555.4, AC008555.3, LINC00904, LINC01838, ZNF30-AS1, ZNF30, AC008555.6, ZNF792, GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7.
- chr20:17,887,363–19,056,796, 43 genes, copy number 5: AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1.
- chr20:24,445,391–64,327,972, 923 genes, copy number 5–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,824. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
